Somatic mutation profile of tumor specimen C3L-05884-54 (aliquot CPT0416170002) from CPTAC case C3L-05884, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 53.0 years (19,361 days).
Specimen C3L-05884-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a543abe4-3d86-4057-85a4-015fcba41cc0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05884-50 (Buccal Cell Normal), aliquot CPT0410240001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7d9e8cc-9d49-407a-b8de-82c824a34d0b

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRD8 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1313721340, COSV50147794; called by muse, mutect2, varscan2
- FAM149B1 | c.1391C>T p.T464M | Missense Mutation (SNP) | VAF 64/135 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749780762; called by muse, mutect2, varscan2
- NEURL3 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 96/238 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs1218604071; called by muse, mutect2, varscan2
- VWA3A | c.2491G>A p.V831M | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs771419391, COSV55387866; called by muse, mutect2, varscan2
- CSNK1G1 | c.95C>G p.S32* | Nonsense Mutation (SNP) | VAF 95/224 reads (42%) | called by muse, mutect2, varscan2
- TAF6 | c.1898C>G p.S633W | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- TOPBP1 | c.1888T>A p.S630T | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HLA-DPB2 | n.396G>A | RNA (SNP) | VAF 53/115 reads (46%) | called by muse, mutect2, varscan2
